Somatic mutation profile of tumor specimen TARGET-15-SJMPAL011914-09A (aliquot TARGET-15-SJMPAL011914-09A-01D) from TARGET case TARGET-15-SJMPAL011914, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,613 days).
Specimen TARGET-15-SJMPAL011914-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b131434e-b186-4136-8991-3c5cf8efd594.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL011914-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL011914-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43a4e157-ad74-4af4-b283-d2692ba1e367

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Silent 3, Frame Shift Ins 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.4258C>T p.R1420* | Nonsense Mutation (SNP) | VAF 95/100 reads (95%) | catalogued as COSV54393900; called by muse, mutect2, varscan2
- WT1 | c.1104_1105insACTGGTCC p.S369Tfs*71 | Frame Shift Ins (INS) | VAF 51/132 reads (39%) | catalogued as COSV60065450, COSV60070013, COSV60076917, COSV99070067; called by pindel, varscan2
- WT1 | c.1073_1074insGG p.P360Cfs*4 | Frame Shift Ins (INS) | VAF 51/127 reads (40%) | catalogued as COSV60065649, COSV60065719, COSV60065736, COSV60066137, COSV60067652, COSV60068117, COSV60069984, COSV60070623, COSV60071183, COSV60072151, COSV60083061, COSV60084162, COSV99070056, COSV99070061, COSV99070065; called by pindel, varscan2
- ATP10B | c.869-2A>C p.X290_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- CCDC141 | c.3827G>T p.C1276F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2
- FAM83G | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITIH6 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.597); called by muse, mutect2
- JADE2 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC28 | c.339_340insGG p.R114Gfs*6 | Frame Shift Ins (INS) | VAF 45/105 reads (43%) | called by mutect2, pindel, varscan2
- OTUD6A | c.40C>A p.R14S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHF6 | c.49T>A p.C17S | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETD2 | c.6731G>T p.S2244I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- TRRAP | c.1317C>A p.G439= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- USH2A | c.7428C>T p.G2476= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as rs150372183; called by muse, mutect2, varscan2
- ZDHHC1 | c.894C>A p.L298= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs772142920, COSV52084778; called by muse, mutect2, varscan2
- FAM177A1 | c.-28-16C>T | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- LRIG3 | c.1801+132T>A | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- YY1AP1 | c.48-129C>A | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2
